Somatic mutation profile of tumor specimen BA2217D (aliquot aq-BA2217D) from BEATAML1.0 case 2538, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Primary diagnosis: Acute myeloid leukemia with mutated CEBPA; Tissue or organ of origin: Bone marrow; Age at diagnosis: 47.2 years (17,224 days).
Specimen BA2217D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9a167d14-4e12-459f-840f-696a3f503ccb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2324D (Solid Tissue Normal), aliquot aq-BA2324D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2a6ca2d9-cf74-40b6-8729-6dcaff45f697

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Silent 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STAT5B | c.1924A>C p.N642H | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.949); catalogued as rs938448224, COSV53180204; ClinVar: pathogenic / uncertain significance; called by muse, mutect2
- JAK3 | c.1533G>T p.M511I | Missense Mutation (SNP) | VAF 16/233 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV71685384, COSV71685422, COSV71685783; called by muse, mutect2
- KCTD16 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs868542964, COSV72579641; called by muse, mutect2, varscan2
- MDGA2 | c.2981C>A p.A994E (on ENST00000399232 / NM_001113498.2; = p.A696E on NM_182830.4) | Missense Mutation (SNP) | VAF 63/117 reads (54%) | SIFT tolerated (0.17); PolyPhen benign (0.133); catalogued as rs755407894; called by muse, mutect2, varscan2
- MYO7B | c.775C>T p.L259F | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67351038; called by muse, mutect2, varscan2
- WT1 | c.1134_1137dup p.M380Lfs*10 | Frame Shift Ins (INS) | VAF 32/218 reads (15%) | called by mutect2, varscan2
- CUBN | c.5517C>T p.S1839= | Silent (SNP) | VAF 43/203 reads (21%) | catalogued as rs754868648, COSV64727422; called by muse, mutect2, varscan2
